Gene-level copy-number profile of tumor specimen TCGA-OR-A5L8-01A from TCGA case TCGA-OR-A5L8, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 36.9 years (13,472 days).
Specimen TCGA-OR-A5L8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.eb2d3b3f-7cf2-44b8-a071-a9590f32e0fa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5L8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b2bf0724-9bac-4d4d-9f27-badb6bf42088

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 4: 32,529; copy number 6: 16,553; copy number 8: 7,259; copy number 9: 3,228; copy number 10: 74; copy number 11: 102; copy number 13: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5L8-01A-11D-A29H-01): tumor purity 0.91, ploidy 2.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,473 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,609,479–175,941,037, 6 genes, copy number 9: RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1.
- chr5:58,198–181,342,213, 2,985 genes, copy number 9 (broad region; genes not listed).
- chr8:150,584–5,670,140, 74 genes, copy number 11 (broad region; genes not listed).
- chr8:6,403,551–7,029,489, 28 genes, copy number 11: AC016065.1, MCPH1, AC016065.2, ANGPT2, AC018398.2, AF287957.1, MCPH1-AS1, MIR8055, AGPAT5, MIR4659A, MIR4659B, AF233439.2, XKR5, GS1-24F4.2, DEFB1, RPL23AP96, DEFA6, AF233439.1, DEFA4, DEFA8P, DEFA9P, DEFA10P, DEFA1, DEFT1P, DEFA1B, DEFT1P2, DEFA3, DEFA11P.
- chr8:9,899,871–12,034,612, 74 genes, copy number 10 (broad region; genes not listed).
- chr14:18,333,726–22,513,998, 306 genes, copy number 9–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
